Somatic mutation profile of tumor specimen 0DPZU1 from CCDI case PBCADA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Gastrointestinal stromal tumor, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 17.5 years (6,377 days).
Specimen 0DPZU1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 805321bf-ce26-4fbc-9e2a-f0f08b554ef3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPZU6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef479beb-4a07-49b0-a148-0e9158f5976d

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Splice Site 1, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM47E-STBD1 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 156/442 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs913328924; called by muse, varscan2
- SH3RF2 | c.744+2T>A p.X248_splice | Splice Site (SNP) | VAF 70/740 reads (9%) | catalogued as COSV63038710; called by muse, mutect2
- ACSM6 | c.314C>A p.T105N | Missense Mutation (SNP) | VAF 29/588 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, mutect2
- HNF1B | c.1225G>A p.G409S | Missense Mutation (SNP) | VAF 157/551 reads (28%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- PPP1R12A | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 266/740 reads (36%) | called by mutect2, varscan2
- ZFYVE16 | c.2061C>A p.I687= | Silent (SNP) | VAF 93/604 reads (15%) | catalogued as COSV62018014; called by muse, mutect2, varscan2
- TTC17 | c.531+10G>A | Intron (SNP) | VAF 215/856 reads (25%) | called by muse, mutect2, varscan2
- TYW1B | c.-21C>G | 5'UTR (SNP) | VAF 164/494 reads (33%) | called by muse, mutect2, varscan2
